CPTAC case 11LU016 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fd0cd324-0557-4946-8ea9-55ad2032a31b

Demographics
Sex at birth: male; Race: asian; Year of birth: 1953; Vital status: Dead; Days to death: 445 days (1.2 years); Year of death: 2016; Cause of death: Cancer Related; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 62.2 years (22,733 days); Year of diagnosis: 2015; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 445 days (1.2 years); Progression or recurrence: no; Days to last follow up: 445 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 1.4 cm); Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 9; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 445 days (1.2 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 51 kg; Height: 165 cm; BMI: 18.73.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample 93e30fd5-e57e-4503-a175-863c7d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 4 days; Initial weight: 230 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide 93e30fd5-e57e-4503-a175-863c7d_D1_D1: Section location: not specified; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample 953d4247-a33a-4caa-a0de-2f19cd: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Days to sample procurement: 4 days; Method of sample procurement: Blood Draw.
- Sample 9e1a4513-58c1-4968-84c6-8ab96b: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
